Somatic mutation profile of tumor specimen BA3214D (aliquot aq-BA3214D) from BEATAML1.0 case 2820, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Tissue or organ of origin: Bone marrow.
Specimen BA3214D: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58aef951-940c-48ce-9dde-cac03fb58d75.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3377D (Solid Tissue Normal), aliquot aq-BA3377D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/181e7b59-d60e-4615-8442-23bc6978ecdf

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5608C>T p.R1870W (on ENST00000358273 / NM_001042492.3; = p.R1849W on NM_000267.3) | Missense Mutation (SNP) | VAF 136/147 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1049849034, COSV62192493; called by muse, mutect2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 145/304 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111033280, CM080595, COSV56330658, COSV56386823, COSV56410469; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CELSR1 | c.6031C>G p.H2011D | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as COSV99417777; called by muse, mutect2
- CLVS2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 133/259 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.352); catalogued as rs1027663142, COSV51568074; called by muse, mutect2, varscan2
- COL9A1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 196/384 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs773143381, COSV61833606, COSV61835935; called by muse, mutect2, varscan2
- EP300 | c.4452G>A p.K1484= | Splice Region (SNP) | VAF 12/209 reads (6%) | catalogued as COSV54348832; called by muse, mutect2
- ETV6 | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765702; called by muse, varscan2
- GATA2 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 96/177 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62002961, COSV62003975; called by muse, mutect2, varscan2
- GNB1 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 142/213 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1231842600, COSV101060718, COSV66101380; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- HRNR | c.1500G>C p.Q500H | Missense Mutation (SNP) | VAF 41/701 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs777678083; called by muse, mutect2
- HUWE1 | c.12005G>A p.R4002H | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782633218, COSV53337404, COSV53359871; called by muse, mutect2
- MYO16 | c.4119C>G p.D1373E | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV62758454; called by muse, mutect2
- PIAS2 | c.1666C>G p.L556V | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs779420631, COSV100244832; called by muse, mutect2
- STK33 | c.874C>G p.P292A | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1425832205; called by muse, mutect2
- TAF1L | c.3160G>C p.E1054Q | Missense Mutation (SNP) | VAF 26/577 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.348); catalogued as COSV54258058, COSV99644315; called by muse, mutect2
- ZC3H8 | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV99735176; called by muse, mutect2
- ANKRD26 | c.820C>G p.P274A | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2
- CACNA1E | c.5212C>G p.P1738A | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2
- FLG | c.9793G>C p.G3265R | Missense Mutation (SNP) | VAF 40/718 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.353); called by muse, mutect2
- KPNB1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- MUC16 | c.28279G>C p.V9427L | Missense Mutation (SNP) | VAF 46/731 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.373); called by muse, mutect2
- MUC16 | c.21840G>C p.R7280S | Missense Mutation (SNP) | VAF 23/449 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.059); called by muse, mutect2
- MUC16 | c.13488G>C p.M4496I | Missense Mutation (SNP) | VAF 27/551 reads (5%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- MYO16 | c.4776C>G p.H1592Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- NFAT5 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- NINL | c.3659C>G p.S1220* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- PLEC | c.4278C>G p.Y1426* (on ENST00000322810 / NM_201380.4; = p.Y1316* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- RASA2 | c.1133C>G p.A378G | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2
- RP1L1 | c.1279G>C p.G427R | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.021); called by muse, mutect2
- STK39 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- TRDN | c.1543C>G p.Q515E | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); called by muse, mutect2
- TTLL3 | c.1350C>G p.N450K | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.076); called by muse, mutect2
- UGGT2 | c.2637C>G p.F879L | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- ZFHX3 | c.3081G>C p.W1027C | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACACB | c.3534C>G p.A1178= | Silent (SNP) | VAF 28/265 reads (11%) | called by muse, mutect2, varscan2
- ATP7A | c.90T>A p.I30= | Silent (SNP) | VAF 11/319 reads (3%) | called by muse, mutect2
- CDH4 | c.2130G>C p.V710= | Silent (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
- LPA | c.1080G>A p.P360= | Silent (SNP) | VAF 12/267 reads (4%) | catalogued as rs764520726, COSV100308347; called by muse, mutect2
- LZTS1 | c.1482C>G p.P494= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs147895092; called by muse, mutect2, varscan2
- PREP | c.1845G>C p.G615= (on ENST00000369110; = p.G681= on NM_002726.5) | Silent (SNP) | VAF 24/313 reads (8%) | called by muse, mutect2
- SREBF2 | c.2190C>G p.G730= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- TDRD5 | c.624G>A p.P208= | Silent (SNP) | VAF 129/275 reads (47%) | catalogued as rs1453107837, COSV54239564; called by muse, mutect2, varscan2
- TMEM198 | c.978C>G p.T326= | Silent (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- ZFHX3 | c.1842G>C p.G614= | Silent (SNP) | VAF 12/340 reads (4%) | called by muse, mutect2
